Somatic mutation profile of tumor specimen TCGA-86-8055-01A (aliquot TCGA-86-8055-01A-11D-2238-08) from TCGA case TCGA-86-8055, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.7 years (29,124 days).
Specimen TCGA-86-8055-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c0621b6-795f-4a9c-9e69-efaf9e7ca72c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8055-10A (Blood Derived Normal), aliquot TCGA-86-8055-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f2ff351-e12c-4493-ae70-ba531a83c479

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, 5'UTR 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC2H1 | c.10142C>T p.P3381L | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs368631447, CM133149; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 362/510 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 26/102 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ANKRA2 | c.93A>C p.K31N | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV57141279; called by muse, mutect2
- CACNA1H | c.3697G>A p.D1233N | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.106); catalogued as rs768716174, COSV100673379; ClinVar: uncertain significance; called by muse, varscan2
- CIT | c.5921G>A p.R1974H | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1310332241, COSV55873090; called by muse, mutect2
- COL3A1 | c.2207G>A p.S736N | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV58591041; called by muse, mutect2
- CYP4F2 | c.169C>G p.R57G | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV50001678; called by muse, mutect2
- ERICH3 | c.2617G>C p.D873H | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV58610324; called by muse, mutect2, varscan2
- FBXO17 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 15/146 reads (10%) | catalogued as rs549735835, COSV53070190, COSV53071564; called by muse, mutect2, varscan2
- GPR37 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 31/324 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1347278490, COSV58257593; called by muse, mutect2, varscan2
- JPH1 | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1228915983, COSV60612154; called by muse, mutect2, varscan2
- KAT7 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); catalogued as COSV99372045; called by muse, mutect2
- KAT7 | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV99372047; called by muse, mutect2
- LRP2BP | c.794T>G p.F265C | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV60750208; called by muse, mutect2
- MAS1L | c.244G>C p.A82P | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.884); catalogued as COSV65809115; called by muse, mutect2, varscan2
- MMP24 | c.876C>G p.H292Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55771035; called by mutect2, varscan2
- MUC16 | c.33229C>A p.H11077N | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.007); catalogued as COSV67475611; called by muse, mutect2
- PACSIN2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs1322605656, COSV54320433; called by muse, mutect2, varscan2
- PCDHGA12 | c.2662G>A p.V888M | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs116366286, COSV52745903; called by muse, mutect2
- PCDHGC4 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV52742843; called by muse, mutect2
- PLEC | c.9443C>G p.A3148G (on ENST00000322810 / NM_201380.4; = p.A3038G on NM_000445.5) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV59652312; called by muse, mutect2, varscan2
- PROSER1 | c.1384C>T p.L462F | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV61488260; called by muse, mutect2, varscan2
- PSMD13 | c.801G>C p.Q267H | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.75); catalogued as COSV61501259; called by muse, mutect2, varscan2
- PTK2B | c.1828A>T p.M610L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV57759358; called by muse, mutect2
- PTK2B | c.1830G>T p.M610I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100593642, COSV100594362; called by muse, mutect2
- ROCK1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 106/291 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV101296619, COSV67695496; called by muse, mutect2, varscan2
- RPL14 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.095); catalogued as COSV59083264; called by muse, mutect2
- TTN | c.93861A>T p.R31287S (on ENST00000591111; = p.R23863S on NM_003319.4) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | PolyPhen probably damaging (0.996); catalogued as COSV60150176; called by muse, mutect2
- UBA6 | c.919A>C p.K307Q | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as COSV59178573; called by muse, mutect2, varscan2
- ZFPM1 | c.1054A>G p.S352G | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1180036961, COSV60323191; called by muse, mutect2, varscan2
- ZNF649 | c.518A>C p.N173T | Missense Mutation (SNP) | VAF 34/347 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV56816596; called by muse, mutect2, varscan2
- SPATA31A1 | c.944G>A p.G315D | Missense Mutation (SNP) | VAF 38/578 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.436); called by muse, mutect2
- DDX53 | c.1536C>T p.D512= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV60069467; called by muse, mutect2, varscan2
- DNAH8 | c.7929T>G p.T2643= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as COSV59457576; called by muse, mutect2, varscan2
- FGF18 | c.189G>A p.G63= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV51127140; called by muse, varscan2
- IGKV6D-41 | c.216C>G p.S72= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- MAP1B | c.2892G>A p.V964= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV57101196; called by muse, mutect2, varscan2
- MRPL38 | c.753G>A p.T251= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs540793162, COSV53933612; called by muse, mutect2, varscan2
- PPIL3 | c.264T>G p.S88= (on ENST00000392283 / NM_130906.3; = p.S92= on NM_032472.4) | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV53769647; called by muse, mutect2, varscan2
- TMEM132B | c.903C>G p.V301= | Silent (SNP) | VAF 34/490 reads (7%) | catalogued as COSV54757808; called by muse, mutect2
- ZFYVE16 | c.3312G>A p.L1104= | Silent (SNP) | VAF 29/183 reads (16%) | catalogued as COSV62016141; called by muse, mutect2, varscan2
- NPHP3 | c.-1C>T | 5'UTR (SNP) | VAF 17/50 reads (34%) | catalogued as rs766279003, COSV100447295; called by muse, mutect2, varscan2
- PLXNA4 | c.1372-87002T>A | Intron (SNP) | VAF 10/106 reads (9%) | catalogued as COSV100322688, COSV100326545; called by muse, mutect2
